Somatic mutation profile of tumor specimen MMRF_1338_2_BM_CD138pos (aliquot MMRF_1338_2_BM_CD138pos_T1_KHS5U_K15161) from MMRF case MMRF_1338, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 31.0 years (11,322 days).
Specimen MMRF_1338_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84c2a40b-3b33-4f25-8c1a-21b27f784c22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1338_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1338_1_PB_Whole_C2_KAS5U_L00654; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c82d7527-b274-4670-b994-44513986a817

The open-access MAF lists 65 somatic variants for this specimen: 18 protein-altering or splice-affecting, 11 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 18, Missense Mutation 16, Intron 11, Silent 11, 5'UTR 3, Nonsense Mutation 2, 5'Flank 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNB | c.4282G>A p.G1428S | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747673269; called by muse, mutect2, varscan2
- FRS3 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 76/165 reads (46%) | catalogued as rs779642151; called by muse, mutect2, varscan2
- MEGF8 | c.4202C>T p.S1401L (on ENST00000251268 / NM_001271938.2; = p.S1334L on NM_001410.3) | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs768453015, COSV52094838; called by muse, mutect2, varscan2
- MYO3A | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs912569262; called by muse, mutect2, varscan2
- PEPD | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1207919311, COSV54888728; called by muse, mutect2
- PTPRD | c.135C>A p.C45* | Nonsense Mutation (SNP) | VAF 74/173 reads (43%) | catalogued as COSV61962191; called by muse, mutect2, varscan2
- RPL10 | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV50010499; called by muse, mutect2, varscan2
- TENM3 | c.6593G>A p.R2198H | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.98); catalogued as rs201676320, COSV69308961, COSV69312882; called by muse, mutect2
- TIGD3 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs982405240; called by muse, mutect2, varscan2
- CXCR5 | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 130/392 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- DOK3 | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- MEF2A | c.1130C>G p.S377C (on ENST00000557942 / NM_001319206.2; = p.S371C on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PGLYRP2 | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PPP1R9A | c.2665C>A p.L889I | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SPTBN1 | c.5162C>T p.A1721V | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENT5C | c.290T>A p.V97E | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- WDFY3 | c.7099G>T p.D2367Y | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZDHHC5 | c.82A>G p.T28A | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ARFGEF3 | c.2742C>T p.S914= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as COSV52466033; called by muse, mutect2, varscan2
- CFD | c.579G>A p.L193= | Silent (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- CXCR5 | c.504C>A p.I168= | Silent (SNP) | VAF 120/342 reads (35%) | called by muse, varscan2
- CXCR5 | c.558C>G p.L186= | Silent (SNP) | VAF 162/454 reads (36%) | catalogued as COSV52682477; called by muse, varscan2
- DOK3 | c.1065C>T p.H355= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as rs774347697; called by muse, mutect2, varscan2
- GPAA1 | c.795G>A p.L265= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs911001673; called by muse, mutect2, varscan2
- IGLV3-1 | c.72T>G p.T24= | Silent (SNP) | VAF 70/192 reads (36%) | catalogued as rs191429645; called by muse, mutect2
- NLRX1 | c.1020C>T p.V340= | Silent (SNP) | VAF 29/172 reads (17%) | called by muse, mutect2, varscan2
- SLC7A10 | c.210C>G p.G70= | Silent (SNP) | VAF 14/165 reads (8%) | called by muse, mutect2
- TTLL2 | c.897C>T p.N299= | Silent (SNP) | VAF 19/344 reads (6%) | catalogued as rs1241868846; called by muse, mutect2
- ZGLP1 | c.15G>A p.Q5= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as COSV58532862; called by muse, mutect2, varscan2
- BEND4 | c.*1400A>C | 3'UTR (SNP) | VAF 62/131 reads (47%) | called by muse, mutect2, varscan2
- CD36 | c.-89-196T>G | Intron (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2
- CMC1 | c.201-176T>C | Intron (SNP) | VAF 23/152 reads (15%) | called by muse, mutect2, varscan2
- COG8 | c.*379G>C | 3'UTR (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- DMAC1 | chr9:7800089 T>C | 5'Flank (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- DSG2 | c.2335-11T>C | Intron (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- EPC2 | c.*1178A>T | 3'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- ERCC1 | c.602+10G>A | Intron (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+2314A>G | Intron (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- FSTL4 | c.1340-29G>A | Intron (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- GLYR1 | c.*253T>A | 3'UTR (SNP) | VAF 57/140 reads (41%) | called by muse, mutect2, varscan2
- INPP4B | chr4:142024796 T>C | 3'Flank (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- KMT2A | c.432+2075T>G | Intron (SNP) | VAF 60/184 reads (33%) | called by muse, mutect2, varscan2
- MARF1 | chr16:15643493 A>G | 5'Flank (SNP) | VAF 40/78 reads (51%) | called by muse, varscan2
- MLEC | c.*3529A>T | 3'UTR (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- MLEC | c.*3530A>C | 3'UTR (SNP) | VAF 33/87 reads (38%) | called by muse, mutect2, varscan2
- NEDD9 | c.-27A>G | 5'UTR (SNP) | VAF 78/220 reads (35%) | called by muse, mutect2, varscan2
- NELFCD | c.230+38G>T | Intron (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- OR8J1 | c.*57del | 3'UTR (DEL) | VAF 29/87 reads (33%) | called by mutect2, pindel, varscan2
- PCSK4 | c.189+119C>G | Intron (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2
- RAPGEF6 | c.*2176C>T | 3'UTR (SNP) | VAF 17/47 reads (36%) | catalogued as rs543725412; called by muse, mutect2, varscan2
- RNF39 | c.-82G>C | 5'UTR (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- RPL15 | c.*517_*536del | 3'UTR (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- SH3PXD2B | c.*2832G>A | 3'UTR (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- SLC22A17 | n.1341C>T | RNA (SNP) | VAF 43/118 reads (36%) | catalogued as rs757846010; called by muse, mutect2, varscan2
- SLC48A1 | c.*128G>A | 3'UTR (SNP) | VAF 30/227 reads (13%) | catalogued as rs757885433; called by muse, mutect2, varscan2
- SLCO2A1 | c.*1067C>T | 3'UTR (SNP) | VAF 55/101 reads (54%) | called by muse, mutect2, varscan2
- SORCS1 | c.3371+377C>T | Intron (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- SS18L1 | c.-7C>T | 5'UTR (SNP) | VAF 11/81 reads (14%) | catalogued as rs374946407; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*1965T>A | 3'UTR (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- TAB2 | c.*165C>T | 3'UTR (SNP) | VAF 14/79 reads (18%) | catalogued as rs1224740857; called by muse, mutect2, varscan2
- TSTD2 | c.*2165A>T | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- UCMA | c.*29A>G | 3'UTR (SNP) | VAF 92/206 reads (45%) | called by muse, mutect2, varscan2
- VGLL3 | c.*7738G>A | 3'UTR (SNP) | VAF 8/70 reads (11%) | catalogued as rs1206747739; called by muse, mutect2
- VMP1 | c.*114C>T | 3'UTR (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2
- ZC3H13 | c.4672+1005A>G | Intron (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
